Somatic mutation profile of tumor specimen TARGET-20-PASZEB-09A (aliquot TARGET-20-PASZEB-09A-01D) from TARGET case TARGET-20-PASZEB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,508 days).
Specimen TARGET-20-PASZEB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f87b27f-f2df-440f-9b3d-fecfe4b8561c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZEB-14A (Bone Marrow Normal), aliquot TARGET-20-PASZEB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8d416ec-6775-41d0-8de3-3171d5a60806

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2132_2133insGG p.H712Afs*37 | Frame Shift Ins (INS) | VAF 76/110 reads (69%) | catalogued as COSV100648321; called by mutect2, pindel, varscan2
